Somatic mutation profile of tumor specimen TCGA-AA-3696-01A (aliquot TCGA-AA-3696-01A-01W-0900-09) from TCGA case TCGA-AA-3696, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-AA-3696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2be0fbcd-cc32-40e5-a157-02d9acd4b857.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3696-10A (Blood Derived Normal), aliquot TCGA-AA-3696-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef158d65-6019-4b1b-9365-6f64d0e1e8bf

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 23, Splice Site 4, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 44/107 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045586, COSV59537585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 46/101 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- TP63 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs121908841, CM001823, CM030108, COSV53215406, COSV53221840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM32 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764664916, COSV65947563, COSV65954225; called by muse, mutect2, varscan2
- APC | c.835-1G>A p.X279_splice | Splice Site (SNP) | VAF 31/83 reads (37%) | catalogued as CS930758, COSV99967580; called by muse, mutect2, varscan2
- APC | c.4156_4159dup p.C1387* | Frame Shift Ins (INS) | VAF 30/109 reads (28%) | catalogued as COSV57398657; called by mutect2, pindel, varscan2
- BCLAF3 | c.1882G>T p.D628Y (on ENST00000379682 / NM_001367774.1; = p.D599Y on NM_198279.3) | Missense Mutation (SNP) | VAF 288/705 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV61414984; called by muse, mutect2, varscan2
- BICD1 | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55689763; called by muse, mutect2, varscan2
- CHD6 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 123/222 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV58554020; called by muse, mutect2, varscan2
- COL11A1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1186482291, COSV62180334, COSV62184324; called by muse, mutect2, varscan2
- COL4A5 | c.3283G>T p.G1095C | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60374102; called by muse, mutect2, varscan2
- CSTF1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as rs140246355; called by muse, mutect2, varscan2
- DGKB | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs772215117, COSV51772068; called by muse, mutect2, varscan2
- DOCK4 | c.2914C>T p.R972C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1187348274, COSV70242181; called by muse, mutect2, varscan2
- DSEL | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490040109, COSV59494147; called by muse, mutect2, varscan2
- ESR2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1190163038, COSV50839756, COSV99963063; called by muse, mutect2, varscan2
- FAM47C | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV63731013; called by muse, mutect2, varscan2
- HERC2 | c.4337A>G p.K1446R | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV55353791; called by muse, mutect2, varscan2
- HOMER3 | c.303+2T>G p.X101_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99651038; called by muse, mutect2, varscan2
- IRS4 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs143812272, COSV64535021; called by muse, mutect2, varscan2
- KMT2A | c.6235G>A p.V2079I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1555045463, COSV63282749; called by muse, mutect2, varscan2
- KRT72 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368767777, COSV53374553; called by muse, mutect2, varscan2
- KRTAP6-2 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 66/138 reads (48%) | PolyPhen benign (0); catalogued as COSV58183177; called by muse, mutect2, varscan2
- LPA | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 39/826 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs761691644, COSV100306392; called by muse, mutect2
- LRTM2 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV54564682; called by muse, mutect2, varscan2
- MEMO1 | c.657+1G>T p.X219_splice | Splice Site (SNP) | VAF 80/232 reads (34%) | catalogued as COSV54457591; called by muse, mutect2, varscan2
- MUC17 | c.3256G>T p.A1086S | Missense Mutation (SNP) | VAF 173/559 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV60306846; called by muse, mutect2, varscan2
- MYOM2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs147661043, COSV50717399; called by muse, mutect2, varscan2
- NAV3 | c.4780G>T p.A1594S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV57117237; called by muse, mutect2, varscan2
- NRG1 | c.625T>A p.L209M | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV55178645; called by muse, mutect2, varscan2
- NRK | c.2470C>A p.Q824K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV54608932; called by muse, mutect2, varscan2
- OR4K14 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV59294552; called by muse, mutect2, varscan2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2, varscan2
- PCDH15 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57408530; called by muse, mutect2, varscan2
- PCDHA13 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV56553491; called by muse, mutect2, varscan2
- PCDHA3 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.301); catalogued as COSV63544026; called by muse, mutect2, varscan2
- PCYOX1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773198726, COSV52478441; called by muse, mutect2, varscan2
- PGBD2 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as rs754725497, COSV61401043; called by muse, mutect2, varscan2
- PHF8 | c.2026C>T p.R676W (on ENST00000357988 / NM_001184896.1; = p.R640W on NM_015107.3) | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as rs782204549, COSV57689293; called by muse, mutect2, varscan2
- PLA2G4D | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs143243064, COSV99299786; called by muse, mutect2, varscan2
- RAMP3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs762889499, COSV54245059; called by muse, mutect2
- RANBP17 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV66658609; called by muse, mutect2, varscan2
- RERG | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs376776458; called by muse, varscan2
- RIT2 | c.588_592del p.K198Qfs*60 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | catalogued as rs1472673491; called by mutect2, pindel, varscan2
- RP1 | c.4345G>T p.G1449C | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99607299; called by muse, mutect2, varscan2
- RP1 | c.4346G>T p.G1449V | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99607304; called by muse, mutect2, varscan2
- RSPO1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as rs761409987, COSV62974352, COSV62974548; called by muse, mutect2, varscan2
- RYR2 | c.2645G>T p.R882I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV63675473, COSV63719959; called by muse, mutect2, varscan2
- SAMD9L | c.3836A>T p.K1279I | Missense Mutation (SNP) | VAF 199/651 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV59086033; called by muse, mutect2, varscan2
- SCD5 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200922750, COSV56729846; called by muse, mutect2, varscan2
- SMCHD1 | c.553A>C p.N185H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55270672; called by muse, mutect2, varscan2
- SPO11 | c.882+1G>C p.X294_splice | Splice Site (SNP) | VAF 22/34 reads (65%) | catalogued as COSV100625696; called by muse, mutect2, varscan2
- SVEP1 | c.4090G>A p.A1364T | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV100237895; called by muse, mutect2
- SVIL | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as COSV63449164; called by muse, mutect2, varscan2
- TET1 | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV65390193; called by muse, mutect2, varscan2
- TFPI2 | c.235T>C p.W79R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761474099, COSV55992117; called by muse, mutect2, varscan2
- TLN2 | c.6478G>A p.V2160M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60897071; called by muse, mutect2, varscan2
- TP53BP1 | c.5197G>A p.A1733T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764425387, COSV55505147; called by muse, mutect2, varscan2
- TSC2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200943828; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- UPK1A | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs61744570; called by muse, mutect2, varscan2
- USP54 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs527912423, COSV60440575; called by muse, mutect2, varscan2
- WDR88 | c.1258A>G p.R420G | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV63453095; called by muse, mutect2, varscan2
- WRN | c.2474G>C p.G825A | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53308720; called by muse, mutect2, varscan2
- ZMYM6 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as rs1373039258, COSV64121145; called by muse, mutect2, varscan2
- ZMYM6 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV64122846; called by muse, mutect2, varscan2
- NRBF2 | c.420_421del p.L141Tfs*9 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by pindel, varscan2
- ARHGAP12 | c.2385G>A p.E795= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV60966889; called by muse, mutect2, varscan2
- ATRAID | c.409C>T p.L137= (on ENST00000611786; = p.L24= on NM_016085.5) | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs142014101; called by muse, mutect2, varscan2
- BEX4 | c.39C>T p.N13= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as COSV65516042; called by muse, mutect2, varscan2
- CRYBB3 | c.126G>A p.S42= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs746837533, COSV53195682; called by muse, mutect2, varscan2
- DNAJC14 | c.66C>T p.L22= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV57914646; called by muse, mutect2, varscan2
- DOCK4 | c.2673G>A p.L891= | Silent (SNP) | VAF 28/334 reads (8%) | catalogued as COSV101447848; called by muse, mutect2
- FRMPD3 | c.1662C>T p.A554= | Silent (SNP) | VAF 78/192 reads (41%) | catalogued as rs1412001897, COSV52198267; called by muse, mutect2, varscan2
- GOLGA6A | c.1587G>A p.E529= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1329445064; called by muse, mutect2
- GP5 | c.93C>T p.D31= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs759843994, COSV55462295; called by muse, mutect2, varscan2
- KLHL31 | c.1710G>T p.V570= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs948424824, COSV100911769; called by muse, mutect2
- KMT2D | c.7332C>T p.F2444= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV56451705; called by muse, mutect2, varscan2
- LRFN5 | c.2007C>T p.N669= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV53256630, COSV53278716; called by muse, mutect2, varscan2
- MACROD2 | c.501A>G p.S167= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as rs368006162; called by muse, mutect2, varscan2
- MOSPD2 | c.15C>T p.H5= | Silent (SNP) | VAF 111/244 reads (45%) | catalogued as COSV60761167; called by muse, mutect2, varscan2
- NAP1L3 | c.1392G>A p.E464= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV59078053; called by muse, mutect2, varscan2
- NR0B1 | c.324G>A p.S108= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs147442403, COSV66763618; called by muse, mutect2, varscan2
- NUP160 | c.2346C>T p.C782= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV65856488; called by muse, mutect2, varscan2
- PCDH19 | c.855G>A p.T285= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV55272794; called by muse, mutect2, varscan2
- PKDREJ | c.726C>T p.N242= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53553957; called by muse, mutect2, varscan2
- RNF213 | c.5847C>T p.F1949= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs149232232; called by muse, mutect2, varscan2
- SIGLEC7 | c.702C>G p.L234= | Silent (SNP) | VAF 58/73 reads (79%) | catalogued as COSV58318279; called by muse, mutect2, varscan2
- TPRG1 | c.438C>A p.I146= | Silent (SNP) | VAF 84/198 reads (42%) | catalogued as COSV61469490; called by muse, mutect2, varscan2
- ZNF366 | c.210C>T p.V70= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV59219641; called by muse, mutect2, varscan2
- EIF5A | c.-22+785C>T | Intron (SNP) | VAF 19/50 reads (38%) | catalogued as rs1301133167, COSV100222919; called by muse, mutect2, varscan2
- NXF5 | n.957G>A | RNA (SNP) | VAF 87/287 reads (30%) | catalogued as rs774444304, COSV99533962; called by muse, mutect2, varscan2
- SSX6P | n.276C>T | RNA (SNP) | VAF 57/139 reads (41%) | catalogued as rs1460177666; called by muse, mutect2, varscan2
